Somatic mutation profile of tumor specimen 0DPAOF from CCDI case PBCCTV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,192 days).
Specimen 0DPAOF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 194d4f15-e690-421e-a4e7-913d12060d74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAO6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb455ea5-1386-498c-8d1c-d6e532bac903

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN2 | c.525_538del p.Q176Afs*69 (on ENST00000550104; = p.Q16Afs*69 on NM_002973.4) | Frame Shift Del (DEL) | VAF 8/356 reads (2%) | catalogued as rs1566091060; called by mutect2, varscan2*
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 32/1085 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- EIF3F | c.316T>C p.Y106H | Missense Mutation (SNP) | VAF 290/746 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.761); called by muse, varscan2
- FCGR3B | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 130/1595 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.254); called by muse, mutect2
- TYRP1 | c.768T>G p.N256K | Missense Mutation (SNP) | VAF 502/1114 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- NLRP10 | c.1218G>A p.R406= | Silent (SNP) | VAF 23/400 reads (6%) | called by muse, mutect2
- PCDHA13 | c.1449C>T p.D483= | Silent (SNP) | VAF 13/380 reads (3%) | catalogued as COSV56480859; called by muse, mutect2
- CTDNEP1 | c.361-11A>G | Intron (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
